Somatic mutation profile of tumor specimen TCGA-G9-7510-01A (aliquot TCGA-G9-7510-01A-11D-2260-08) from TCGA case TCGA-G9-7510, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.2 years (24,187 days).
Specimen TCGA-G9-7510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53808ca7-b9c0-41f3-a1f2-8381ba64be69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-7510-10A (Blood Derived Normal), aliquot TCGA-G9-7510-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/728837de-53f0-4b31-9668-66c8ac0177a1

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.805T>C p.S269P | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV57171011; called by muse, mutect2, varscan2
- AKAP6 | c.5133C>G p.I1711M | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV55206566; called by muse, mutect2
- ATM | c.8810T>G p.V2937G | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53730082, COSV53759641; called by muse, mutect2, varscan2
- BDP1 | c.7787C>T p.A2596V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV62429294; called by muse, mutect2, varscan2
- CCDC180 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256020450, COSV100827228, COSV63827424; called by muse, mutect2, varscan2
- CFAP45 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as rs1235504887, COSV63648244; called by muse, mutect2
- CPT1C | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV54917954; called by muse, mutect2
- CSGALNACT1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs867466413, COSV59974581; called by muse, mutect2
- GAN | c.652A>T p.M218L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101633988, COSV73720761; called by muse, mutect2, varscan2
- HSP90AB1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV62333515; called by muse, mutect2, varscan2
- HUWE1 | c.4006A>G p.M1336V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs782123207, COSV53336727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL20RB | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763416984, COSV59046840; called by muse, mutect2, varscan2
- IMP3 | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59188916; called by muse, mutect2, varscan2
- INVS | c.1499G>C p.G500A | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52438792; called by muse, mutect2
- KIF5B | c.2840T>C p.V947A | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56651203; called by muse, mutect2
- NDST4 | c.1354C>G p.P452A | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV52110908, COSV52141369; called by muse, mutect2
- NLRP4 | c.1887C>A p.H629Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV56709115; called by muse, mutect2, varscan2
- PDCD1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs190602950, COSV57690777; called by muse, mutect2, varscan2
- PLA2G12B | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 11/187 reads (6%) | catalogued as rs748036872, COSV65978297; called by muse, mutect2
- PLA2G4E | c.2105C>T p.A702V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs767161401, COSV68149111; called by muse, mutect2
- ZCCHC14 | c.710G>C p.G237A (on ENST00000268616; = p.G374A on NM_015144.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV51884430; called by muse, mutect2, varscan2
- ZNF131 | c.1298A>G p.N433S (on ENST00000509156 / NM_001330707.2; = p.N399S on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs1031237718, COSV61001384; called by muse, mutect2, varscan2
- CCND2 | c.117_123del p.Q40Pfs*40 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, pindel, varscan2
- SPOP | c.361_366del p.R121_A122del | In Frame Del (DEL) | VAF 13/107 reads (12%) | called by mutect2, pindel
- FAM237A | c.78C>T p.C26= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs906653929, COSV69304932; called by muse, mutect2, varscan2
- HOXD3 | c.606G>A p.T202= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs759831709, COSV50879075; called by muse, mutect2, varscan2
- TTC38 | c.1188G>A p.E396= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV66843685; called by muse, mutect2, varscan2
- TTN | c.55095T>C p.G18365= (on ENST00000591111; = p.G10941= on NM_003319.4) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV59915347; called by muse, mutect2, varscan2
